Somatic mutation profile of tumor specimen TARGET-20-PAEEYP-09A (aliquot TARGET-20-PAEEYP-09A-01D) from TARGET case TARGET-20-PAEEYP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (567 days).
Specimen TARGET-20-PAEEYP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 747775e7-55ef-4a87-a8b2-6eed96be4475.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAEEYP-14A (Bone Marrow Normal), aliquot TARGET-20-PAEEYP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2be94ff8-3ed4-4d93-aa27-33abf57fcefd

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 20/244 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2
- C16orf96 | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs796479528, COSV71472598; called by muse, mutect2
- OBSCN | c.8912G>A p.R2971Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs202236984, COSV52825882; called by muse, mutect2, varscan2
- OBSCN | c.21288dup p.K7097* | Frame Shift Ins (INS) | VAF 23/56 reads (41%) | catalogued as rs756752674; called by mutect2, pindel, varscan2
- SETD2 | c.5007G>T p.Q1669H | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57435514; called by muse, mutect2, varscan2
